Somatic mutation profile of tumor specimen 0DPU2Y from CCDI case PBCEET, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 7.2 years (2,648 days).
Specimen 0DPU2Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3bf87fb1-e016-4618-8b7a-f20d35a8a836.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPU2M (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f03bbc0-f423-4627-bae3-cf42613bf31b

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 3, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 87/211 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PDGFRA | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 24/364 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV57265219, COSV57268286, COSV57271923; called by muse, mutect2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 129/308 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 96/268 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121918453, CM013418, CM090463, COSV61004775, COSV61004869, COSV61006317; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- COL8A1 | c.2047G>C p.E683Q | Missense Mutation (SNP) | VAF 45/278 reads (16%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.813); catalogued as COSV53742264; called by muse, mutect2, varscan2
- EDC4 | c.2605C>T p.R869C | Missense Mutation (SNP) | VAF 124/300 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as rs371369902; called by muse, mutect2, varscan2
- HK1 | c.2455G>A p.V819I | Missense Mutation (SNP) | VAF 94/243 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs771865870, COSV53854807; called by muse, varscan2
- HRNR | c.2971C>T p.R991C | Missense Mutation (SNP) | VAF 87/226 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs373485996, COSV64258660; called by muse, mutect2, varscan2
- KCNJ1 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 131/337 reads (39%) | catalogued as rs201707868, CM095055, COSV60662768; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MAP2K3 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 122/613 reads (20%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs779727093; called by muse, mutect2
- NPC2 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 92/258 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as rs747314957; called by muse, mutect2, varscan2
- PDGFRA | c.863A>G p.Y288C | Missense Mutation (SNP) | VAF 32/349 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57264810; called by muse, mutect2
- PPP1R9B | c.1262G>A p.G421E | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV57541722; called by muse, mutect2, varscan2
- ARID3C | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GAS2L2 | c.1471G>T p.V491F | Missense Mutation (SNP) | VAF 69/141 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- NF1 | c.5533A>G p.I1845V (on ENST00000358273 / NM_001042492.3; = p.I1824V on NM_000267.3) | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.28); called by muse, mutect2
- RBM25 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 46/292 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- USP15 | c.325G>A p.G109S | Missense Mutation (SNP) | VAF 119/291 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ANO9 | c.960C>A p.L320= | Silent (SNP) | VAF 96/226 reads (42%) | called by muse, mutect2, varscan2
- GLT1D1 | c.228C>A p.I76= | Silent (SNP) | VAF 133/299 reads (44%) | catalogued as COSV55888811; called by muse, mutect2, varscan2
- RREB1 | c.4440G>A p.A1480= | Silent (SNP) | VAF 75/193 reads (39%) | catalogued as rs187170823; called by muse, mutect2, varscan2
- UBP1 | c.*43G>A | 3'UTR (SNP) | VAF 125/277 reads (45%) | catalogued as rs549763713; called by muse, mutect2, varscan2
